Somatic mutation profile of tumor specimen 6eaf19bf-dd93-4b0b-93c5-e2bca3 (aliquot 6eaf19bf-dd93-4b0b-93c5-e2bca3_D6) from CPTAC case 05BR043, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 50.0 years (18,249 days).
Specimen 6eaf19bf-dd93-4b0b-93c5-e2bca3: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac1c997e-fa0d-4600-a6d7-2fb694e0dfe0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen fab8a1c5-c592-47cd-9d32-54bf14 (Blood Derived Normal), aliquot fab8a1c5-c592-47cd-9d32-54bf14_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16f7cc7f-5994-4202-a74a-d26fc278d4ec

The open-access MAF lists 196 somatic variants for this specimen: 143 protein-altering or splice-affecting, 36 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 36, Frame Shift Del 11, Intron 8, Nonsense Mutation 6, Splice Site 3, In Frame Del 3, 5'UTR 3, 5'Flank 2, 3'Flank 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 103/284 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV61360071; called by muse, mutect2, varscan2
- ALDH1A2 | c.1248G>T p.E416D | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV51079210, COSV51085826; called by muse, mutect2, varscan2
- C19orf81 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs1489628154; called by muse, mutect2, varscan2
- CACNA1D | c.6218G>T p.R2073L (on ENST00000350061 / NM_001128840.3; = p.R2093L on NM_000720.4) | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.201); catalogued as COSV99860377; called by muse, mutect2, varscan2
- COL4A1 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as rs1222297334; called by muse, mutect2, varscan2
- DOCK10 | c.626G>C p.R209P | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51423677; called by muse, mutect2, varscan2
- EFCC1 | c.797C>A p.A266E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs955110100; called by muse, mutect2
- EVI5L | c.1541G>C p.R514P | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1415437550; called by muse, mutect2, varscan2
- FAT3 | c.6732C>A p.S2244R | Missense Mutation (SNP) | VAF 48/439 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.503); catalogued as COSV53078796; called by muse, mutect2, varscan2
- FCGBP | c.10420G>C p.D3474H | Missense Mutation (SNP) | VAF 50/568 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as rs773132965; called by muse, mutect2
- GRIA2 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1408962625, COSV52409063; called by muse, mutect2, varscan2
- HIVEP1 | c.1822A>G p.M608V | Missense Mutation (SNP) | VAF 40/367 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1047092304; called by muse, mutect2, varscan2
- HIVEP1 | c.5698G>A p.V1900I | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs764643335; called by muse, mutect2, varscan2
- LGI3 | c.230C>A p.S77* | Nonsense Mutation (SNP) | VAF 50/218 reads (23%) | catalogued as COSV60443002; called by muse, mutect2, varscan2
- MBD1 | c.1447G>T p.E483* (on ENST00000269468 / NM_001323950.1; = p.E427* on NM_015844.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 122/696 reads (18%) | catalogued as COSV99495349; called by mutect2, varscan2
- NAALADL2 | c.844G>C p.G282R | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101380492; called by muse, mutect2, varscan2
- NECTIN2 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs1568595083; called by muse, mutect2, varscan2
- OR1C1 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 123/351 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV68715678; called by muse, mutect2, varscan2
- PAX7 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748780342, COSV64751584; called by muse, mutect2, varscan2
- PER3 | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.754); catalogued as COSV100728421; called by muse, mutect2, varscan2
- PFKP | c.833C>G p.T278S | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs558520595; called by muse, mutect2, varscan2
- PRDM8 | c.290A>T p.D97V | Missense Mutation (SNP) | VAF 33/365 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs759994498; called by muse, mutect2
- RIC8A | c.1081C>G p.R361G (on ENST00000526104 / NM_001286134.1; = p.R367G on NM_021932.5) | Missense Mutation (SNP) | VAF 119/354 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs768589596, COSV57342504; called by muse, mutect2, varscan2
- RNF169 | c.79C>A p.R27S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.224); catalogued as rs999497987; called by muse, mutect2
- RTL1 | c.3731G>A p.R1244H | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as rs770846607; called by muse, mutect2, varscan2
- SCN10A | c.4288G>A p.G1430S | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs757721860; called by muse, mutect2
- SLC12A4 | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1368965133; called by muse, mutect2, varscan2
- SNTG1 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs144283676, COSV52466221; called by muse, mutect2, varscan2
- STAU2 | c.998G>A p.G333E (on ENST00000524300 / NM_001164380.2; = p.G301E on NM_014393.2) | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747213478, COSV63309368; called by muse, mutect2, varscan2
- STOX2 | c.1016A>G p.E339G | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs767071467; called by muse, mutect2, varscan2
- TRIM14 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 101/233 reads (43%) | catalogued as rs746983430; called by muse, mutect2, varscan2
- UNC13A | c.1350C>A p.N450K | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs1199318266; called by muse, mutect2, varscan2
- VN1R4 | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV60804578; called by muse, mutect2, varscan2
- ZNF484 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60259752; called by muse, mutect2, varscan2
- ZNF831 | c.456C>A p.D152E | Missense Mutation (SNP) | VAF 182/402 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100926344; called by muse, varscan2
- AAGAB | c.499A>T p.N167Y | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ABCA9 | c.1041C>G p.F347L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ADAMTS20 | c.4227G>C p.Q1409H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ADGRD2 | c.2640G>A p.W880* | Nonsense Mutation (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2
- AKR1D1 | c.513T>A p.F171L | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASPG | c.620C>G p.T207R | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ATP9B | c.2979G>C p.M993I | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- BANK1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- BROX | c.146A>C p.D49A | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- C2CD6 | c.20C>G p.T7R | Missense Mutation (SNP) | VAF 170/371 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- CAMKMT | c.438-1G>C p.X146_splice | Splice Site (SNP) | VAF 26/119 reads (22%) | called by muse, mutect2, varscan2
- CNGA1 | c.1366_1388del p.K456Qfs*15 | Frame Shift Del (DEL) | VAF 43/270 reads (16%) | called by mutect2, pindel, varscan2
- COL28A1 | c.1907G>C p.G636A | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- CPS1 | c.2165G>A p.S722N | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRLF1 | c.1042G>C p.G348R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); called by muse, mutect2
- CTNNA1 | c.16_26del p.A6Kfs*7 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- DDC | c.756C>A p.D252E | Missense Mutation (SNP) | VAF 65/328 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DGKA | c.1376_1386del p.L459Yfs*4 | Frame Shift Del (DEL) | VAF 36/143 reads (25%) | called by mutect2, pindel, varscan2
- DMXL2 | c.8367G>A p.M2789I | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DNAH11 | c.7494G>T p.L2498F | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DNAH14 | c.10161G>T p.K3387N (on ENST00000445597; = p.K4395N on NM_001367479.1) | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2
- DPYSL5 | c.1256T>C p.V419A | Missense Mutation (SNP) | VAF 69/308 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFL1 | c.2380C>G p.Q794E | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELFN1 | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 132/532 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVA1C | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- F2 | c.262A>G p.T88A | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GALNT2 | c.1569A>C p.E523D | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCFC2 | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GET3 | c.983C>A p.A328E | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GPR152 | c.176G>C p.R59P | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); called by muse, varscan2
- GUSB | c.1565C>A p.A522D | Missense Mutation (SNP) | VAF 59/544 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HECTD4 | c.3027_3028insC p.L1011Afs*3 | Frame Shift Ins (INS) | VAF 5/55 reads (9%) | called by mutect2, pindel*, varscan2*
- HERPUD2 | c.744_781del p.Q248Hfs*9 | Frame Shift Del (DEL) | VAF 53/217 reads (24%) | called by mutect2, pindel, varscan2
- HLA-E | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ICE1 | c.3793A>T p.K1265* | Nonsense Mutation (SNP) | VAF 38/203 reads (19%) | called by muse, mutect2, varscan2
- KBTBD3 | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- KCTD6 | c.516C>G p.D172E | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KRT82 | c.1357C>G p.P453A | Missense Mutation (SNP) | VAF 126/355 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- LHX1 | c.244A>C p.K82Q | Missense Mutation (SNP) | VAF 182/292 reads (62%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); called by mutect2, varscan2
- LPO | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- MACF1 | c.4622A>G p.E1541G | Missense Mutation (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- MECOM | c.2649A>T p.Q883H (on ENST00000468789 / NM_001105078.4; = p.Q1071H on NM_004991.4) | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MORC3 | c.2585A>C p.K862T | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MTHFD1L | c.1468C>G p.H490D | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTR | c.3406-24_3406-6del | Splice Region (DEL) | VAF 54/346 reads (16%) | called by mutect2, pindel, varscan2
- NEK10 | c.1294A>G p.S432G | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- NME7 | c.716G>C p.C239S | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- NOD1 | c.2528C>T p.T843I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.867); called by muse, varscan2
- NOS2 | c.2116C>A p.P706T | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- NPAP1 | c.2051G>C p.S684T | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- NPRL2 | c.880_889del p.V294Sfs*17 | Frame Shift Del (DEL) | VAF 23/188 reads (12%) | called by pindel, varscan2
- NR1D1 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NTS | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- NUP205 | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- OR4D1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 29/398 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- OSCAR | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PADI4 | c.1865_1881del p.P622Hfs*85 | Frame Shift Del (DEL) | VAF 45/274 reads (16%) | called by mutect2, pindel, varscan2
- PCDHGA4 | c.940A>C p.K314Q | Missense Mutation (SNP) | VAF 105/273 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PCSK5 | c.3782G>A p.R1261K | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PIDD1 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 31/290 reads (11%) | called by muse, mutect2, varscan2
- PIK3C2B | c.710G>C p.R237T | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PIK3CA | c.467T>A p.L156H | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLD5 | c.29C>G p.S10W | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PLEKHG4B | c.2208C>G p.D736E (on ENST00000283426; = p.D1092E on NM_052909.5) | Missense Mutation (SNP) | VAF 37/342 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRDM6 | c.1434_1440delinsTCTA p.F479_K480delinsL | In Frame Del (DEL) | VAF 41/203 reads (20%) | called by pindel, varscan2*
- PROZ | c.80del p.P27Rfs*10 | Frame Shift Del (DEL) | VAF 51/377 reads (14%) | called by pindel, varscan2*
- RANGAP1 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- RBM28 | c.639del p.K213Nfs*45 | Frame Shift Del (DEL) | VAF 15/168 reads (9%) | called by mutect2, pindel
- REV3L | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.056); called by muse, mutect2
- RIMS1 | c.949C>G p.R317G | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RNF2 | c.910-1G>C p.X304_splice | Splice Site (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- RYR1 | c.7644_7657del p.A2549Pfs*48 | Frame Shift Del (DEL) | VAF 107/521 reads (21%) | called by mutect2, pindel, varscan2
- SETDB1 | c.1580G>A p.R527K | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SKIL | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SLC26A8 | c.480C>A p.N160K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SLC28A2 | c.199A>G p.R67G | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- SPTBN5 | c.9908C>G p.A3303G | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SULT1C3 | c.609_611del p.E203del | In Frame Del (DEL) | VAF 31/89 reads (35%) | called by mutect2, pindel, varscan2
- TAF15 | c.1460G>C p.G487A (on ENST00000605844 / NM_139215.3; = p.G484A on NM_003487.4) | Missense Mutation (SNP) | VAF 33/342 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- TARS1 | c.206A>C p.D69A | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- TBC1D25 | c.1604G>C p.S535T | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TENM4 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TOR4A | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, varscan2
- TP53I11 | c.-31-18_-31-1del | Splice Site (DEL) | VAF 17/171 reads (10%) | called by mutect2, pindel
- TPR | c.3058G>C p.D1020H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- TRAPPC12 | c.782_787del p.E261_P262del | In Frame Del (DEL) | VAF 51/167 reads (31%) | called by mutect2, pindel, varscan2
- TRAV22 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIOBP | c.329A>T p.E110V | Missense Mutation (SNP) | VAF 59/384 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- TRO | c.3998C>T p.T1333I | Missense Mutation (SNP) | VAF 112/458 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TRPM7 | c.4019G>A p.R1340K | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); called by muse, mutect2
- TTLL13P | c.453_468del p.C151Wfs*72 | Frame Shift Del (DEL) | VAF 69/215 reads (32%) | called by mutect2, pindel, varscan2
- TULP1 | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 196/508 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TULP4 | c.2075C>G p.A692G | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TYSND1 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- VIRMA | c.3814G>C p.D1272H | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR19 | c.1371C>G p.I457M | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WNK1 | c.3731C>G p.T1244S (on ENST00000315939 / NM_018979.4; = p.T997S on NM_014823.3) | Missense Mutation (SNP) | VAF 118/229 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XRN1 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZCCHC7 | c.211C>G p.Q71E | Missense Mutation (SNP) | VAF 102/298 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZIC5 | c.1794_1830del p.L599Afs*7 | Frame Shift Del (DEL) | VAF 38/129 reads (29%) | called by mutect2, pindel, varscan2
- ZNF345 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF43 | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF638 | c.105C>G p.D35E | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.038); called by muse, mutect2
- ZNF692 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- ZNF780B | c.1748A>T p.K583I | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF831 | c.349A>T p.I117F | Missense Mutation (SNP) | VAF 154/317 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, varscan2
- ZSCAN29 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 90/287 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACLY | c.3093C>T p.V1031= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as rs781877404; called by muse, mutect2
- AP001781.2 | c.114G>T p.P38= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV99500478; called by muse, mutect2, varscan2
- APP | c.984G>A p.R328= | Silent (SNP) | VAF 46/491 reads (9%) | called by muse, mutect2
- ARHGAP33 | c.885C>T p.S295= | Silent (SNP) | VAF 50/436 reads (11%) | catalogued as COSV50138935; called by muse, mutect2, varscan2
- CCDC88C | c.3684G>A p.K1228= | Silent (SNP) | VAF 44/159 reads (28%) | called by muse, mutect2, varscan2
- CEBPE | c.501C>G p.R167= | Silent (SNP) | VAF 48/199 reads (24%) | catalogued as COSV52830098; called by muse, mutect2, varscan2
- CELF5 | c.1146C>G p.V382= | Silent (SNP) | VAF 43/130 reads (33%) | called by muse, mutect2, varscan2
- CHRFAM7A | c.654G>A p.V218= | Silent (SNP) | VAF 90/483 reads (19%) | catalogued as rs762294398; called by muse, mutect2, varscan2
- DMD | c.10254A>G p.V3418= | Silent (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- DYSF | c.2262T>C p.A754= | Silent (SNP) | VAF 58/599 reads (10%) | catalogued as rs141314294; ClinVar: likely benign; called by muse, mutect2
- EHHADH | c.1716C>A p.G572= | Silent (SNP) | VAF 36/644 reads (6%) | called by muse, mutect2
- FCGBP | c.933G>T p.V311= | Silent (SNP) | VAF 80/246 reads (33%) | called by mutect2, varscan2
- FLNC | c.6573G>A p.T2191= | Silent (SNP) | VAF 76/451 reads (17%) | catalogued as rs761680664; called by muse, mutect2, varscan2
- FOXA1 | c.1215C>T p.L405= | Silent (SNP) | VAF 46/552 reads (8%) | called by muse, mutect2
- GADD45G | c.479G>A p.*160= | Silent (SNP) | VAF 78/196 reads (40%) | called by muse, mutect2, varscan2
- GRIP2 | c.2031G>T p.G677= (on ENST00000619221; = p.G580= on NM_001080423.4) | Silent (SNP) | VAF 110/295 reads (37%) | called by muse, mutect2, varscan2
- GUCY2D | c.180C>T p.G60= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as rs753766842, COSV99644263; called by muse, varscan2
- HEY1 | c.765C>T p.L255= | Silent (SNP) | VAF 28/306 reads (9%) | called by muse, mutect2
- IGFN1 | c.2340C>A p.I780= (on ENST00000295591 / NM_001367841.1; = p.I3237= on NM_001164586.2) | Silent (SNP) | VAF 54/253 reads (21%) | catalogued as COSV99811870; called by muse, mutect2, varscan2
- IGHA1 | c.876C>T p.F292= | Silent (SNP) | VAF 50/1442 reads (3%) | catalogued as rs373456912; called by muse, mutect2
- IGHV4-31 | c.234C>T p.T78= | Silent (SNP) | VAF 194/1287 reads (15%) | catalogued as rs745502471; called by muse, varscan2
- NDUFS1 | c.1422G>T p.V474= | Silent (SNP) | VAF 22/143 reads (15%) | called by mutect2, varscan2
- OR1C1 | c.853C>T p.L285= | Silent (SNP) | VAF 124/353 reads (35%) | catalogued as rs1180700843; called by muse, mutect2, varscan2
- OR4D1 | c.123A>T p.G41= | Silent (SNP) | VAF 29/404 reads (7%) | called by muse, mutect2
- PCDHA13 | c.1971C>T p.P657= | Silent (SNP) | VAF 213/484 reads (44%) | catalogued as COSV99166946; called by muse, mutect2, varscan2
- PGD | c.1023G>T p.L341= | Silent (SNP) | VAF 50/289 reads (17%) | called by muse, mutect2, varscan2
- PLCB2 | c.387C>T p.D129= | Silent (SNP) | VAF 88/239 reads (37%) | catalogued as rs769731395; called by muse, mutect2, varscan2
- PRR14L | c.3036A>G p.Q1012= | Silent (SNP) | VAF 74/299 reads (25%) | called by muse, mutect2, varscan2
- RNF208 | c.756G>A p.R252= | Silent (SNP) | VAF 110/301 reads (37%) | catalogued as COSV100763187; called by muse, mutect2, varscan2
- SYNJ2 | c.1254C>G p.P418= | Silent (SNP) | VAF 77/215 reads (36%) | called by muse, mutect2, varscan2
- TIAM2 | c.1161G>A p.T387= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs751233841; called by muse, mutect2
- TRUB2 | c.9T>G p.S3= | Silent (SNP) | VAF 69/128 reads (54%) | called by muse, mutect2, varscan2
- UBR5 | c.5574A>G p.A1858= | Silent (SNP) | VAF 76/252 reads (30%) | called by muse, mutect2, varscan2
- WDFY3 | c.4017C>T p.I1339= | Silent (SNP) | VAF 25/141 reads (18%) | catalogued as rs1471156079; called by muse, mutect2, varscan2
- ZNF234 | c.1443G>A p.E481= | Silent (SNP) | VAF 55/305 reads (18%) | called by muse, mutect2, varscan2
- ZNF81 | c.171G>T p.L57= | Silent (SNP) | VAF 45/230 reads (20%) | catalogued as rs1356920872; called by muse, mutect2, varscan2
- AC097462.3 | n.51+362A>G | Intron (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2, varscan2
- ASPH | c.322+12722A>C | Intron (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- C4A | chr6:32005884 C>T | 3'Flank (SNP) | VAF 126/353 reads (36%) | called by muse, mutect2, varscan2
- COL4A2 | c.1340-499G>A | Intron (SNP) | VAF 127/990 reads (13%) | catalogued as rs751620217, COSV64626158; called by muse, varscan2
- KLHL7 | c.-139C>T | 5'UTR (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- KLK1 | chr19:50818480 G>A | 3'Flank (SNP) | VAF 62/163 reads (38%) | called by muse, mutect2, varscan2
- LIPJ | c.-22A>G | 5'UTR (SNP) | VAF 62/168 reads (37%) | called by muse, mutect2, varscan2
- MRC1 | c.917-171C>T | Intron (SNP) | VAF 24/231 reads (10%) | called by muse, mutect2, varscan2
- PKD1P6 | n.4129G>T | RNA (SNP) | VAF 121/702 reads (17%) | called by mutect2, varscan2
- PTPRN2 | c.2344+5857C>A | Intron (SNP) | VAF 48/414 reads (12%) | called by muse, mutect2
- RUNX1T1 | c.88+13337G>C | Intron (SNP) | VAF 40/458 reads (9%) | called by muse, mutect2
- SEC24B | c.-4C>A | 5'UTR (SNP) | VAF 10/32 reads (31%) | called by muse, varscan2
- SHCBP1L | chr1:182953311 G>T | 5'Flank (SNP) | VAF 17/167 reads (10%) | called by muse, mutect2
- SLC4A10 | c.*95T>A | 3'UTR (SNP) | VAF 59/121 reads (49%) | called by muse, mutect2, varscan2
- SQSTM1 | chr5:179820901 C>A | 5'Flank (SNP) | VAF 18/50 reads (36%) | catalogued as rs762386326; called by muse, varscan2
- ZNF451 | c.186+1959A>G | Intron (SNP) | VAF 34/327 reads (10%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3438G>A | Intron (SNP) | VAF 14/220 reads (6%) | catalogued as COSV100954250; called by muse, mutect2
